Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A77W, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A77W-01A (Primary Tumor).

Oligoastrocytoma, grade III
9382/3
Site: C6CF
Brain, supratentorial NOS
C71.0
path
Brain, frontal lobe
C71.1
8/20/13

Case #

Patient: Age (years): Gender: Female

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by dense white-yellow pieces from left frontal lobe and corpus callosum

Microscopic description:

Received material is consistent with anaplastic oligoastrocytoma, grade III. Ki67 up to 10%

Final diagnosis: Anaplastic oligoastrocytoma: Grade III

Confidential

Reviewer Initials	B24	Date Reviewed: 8/15/13

Source: NCI Genomic Data Commons file 70aaef41-ef7a-4691-9b40-b3c2076de435 (TCGA-P5-A77W.E3E86605-648A-4153-A364-A2C313B9FFF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).